Somatic mutation profile of tumor specimen ALCH-B40K-TTP1-A (aliquot ALCH-B40K-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B40K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.2 years (20,899 days).
Specimen ALCH-B40K-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3067f793-efbb-48b3-8f3c-3d5303f9b3c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B40K-NB1-A (Blood Derived Normal), aliquot ALCH-B40K-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/223ea8a1-18c1-41c8-a911-baf5606606c9

The open-access MAF lists 40 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, In Frame Del 2, 5'UTR 1, Intron 1, Nonsense Mutation 1, Splice Site 1, 5'Flank 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 158/913 reads (17%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- RP1 | c.2700dup p.P901Tfs*2 | Frame Shift Ins (INS) | VAF 46/265 reads (17%) | catalogued as rs797044735; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 104/437 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALPK2 | c.3638C>T p.S1213F | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as COSV64497214; called by muse, mutect2
- CTNNAL1 | c.706A>G p.M236V | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs780557048, COSV100336512; called by muse, mutect2, varscan2
- CTNNBL1 | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63747139; called by muse, mutect2
- FBN3 | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs775885971, COSV99560473; called by muse, varscan2
- FCGR2B | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 260/1082 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs149985147; called by muse, mutect2, varscan2
- IGLON5 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 66/415 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as rs752628449; called by muse, varscan2
- MEGF8 | c.5785C>T p.R1929W (on ENST00000251268 / NM_001271938.2; = p.R1862W on NM_001410.3) | Missense Mutation (SNP) | VAF 31/436 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs529688057, COSV52098301; called by muse, mutect2
- NECAB1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV70241653; called by muse, mutect2, varscan2
- OR2L3 | c.719G>T p.C240F | Missense Mutation (SNP) | VAF 15/428 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63454798; called by muse, mutect2
- PREX1 | c.3184C>T p.R1062W | Missense Mutation (SNP) | VAF 90/620 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs186606574, COSV64253748; called by muse, varscan2
- RPS14 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV100365377; called by muse, mutect2, varscan2
- ASPM | c.5571G>T p.W1857C | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); called by muse, mutect2
- CC2D2A | c.4230G>T p.W1410C | Missense Mutation (SNP) | VAF 41/358 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCNA2 | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 27/397 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2
- CCND1 | c.752T>C p.I251T | Missense Mutation (SNP) | VAF 63/409 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- EEF2K | c.823A>T p.I275F | Missense Mutation (SNP) | VAF 86/512 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EPHB4 | c.1332del p.S445Pfs*6 | Frame Shift Del (DEL) | VAF 31/307 reads (10%) | called by mutect2, pindel, varscan2
- EXD2 | c.1730A>C p.Q577P (on ENST00000312994 / NM_001193362.1; = p.Q452P on NM_018199.3) | Missense Mutation (SNP) | VAF 76/458 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- GDPD5 | c.1417G>T p.V473F | Missense Mutation (SNP) | VAF 99/521 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4B1 | c.490T>G p.L164V | Missense Mutation (SNP) | VAF 48/734 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2
- P2RX1 | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- PCDHA9 | c.2384C>G p.S795* | Nonsense Mutation (SNP) | VAF 65/337 reads (19%) | called by muse, mutect2, varscan2
- RBBP4 | c.374_376del p.G125del | In Frame Del (DEL) | VAF 47/535 reads (9%) | called by mutect2, pindel
- RPS14 | c.388+1G>T p.X130_splice | Splice Site (SNP) | VAF 47/214 reads (22%) | called by muse, mutect2, varscan2
- ZNF219 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF281 | c.974A>C p.K325T | Missense Mutation (SNP) | VAF 115/626 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ADHFE1 | c.399C>T p.A133= | Silent (SNP) | VAF 128/449 reads (29%) | catalogued as rs147458577; called by muse, mutect2, varscan2
- BDKRB1 | c.561C>A p.T187= | Silent (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2
- FOXO3 | c.1014C>T p.D338= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as rs549651273, COSV59626949; called by muse, varscan2
- HAS1 | c.615C>T p.C205= | Silent (SNP) | VAF 55/276 reads (20%) | catalogued as rs1182136818, COSV55787795; called by muse, mutect2, varscan2
- NPEPPS | c.78T>G p.L26= | Silent (SNP) | VAF 43/174 reads (25%) | called by mutect2, varscan2
- POM121L12 | c.267G>A p.P89= | Silent (SNP) | VAF 38/217 reads (18%) | catalogued as rs772385441, COSV101374858, COSV68692323; called by muse, mutect2, varscan2
- SPOCK1 | c.837C>G p.P279= | Silent (SNP) | VAF 58/285 reads (20%) | called by muse, mutect2, varscan2
- VRK3 | c.1341C>T p.A447= | Silent (SNP) | VAF 20/290 reads (7%) | catalogued as rs1210760512; called by muse, mutect2
- PDHB | c.204+42G>T | Intron (SNP) | VAF 183/750 reads (24%) | called by muse, mutect2, varscan2
- TINAG | chr6:54308050 C>A | 5'Flank (SNP) | VAF 52/366 reads (14%) | called by muse, mutect2, varscan2
- ZNF638 | c.-384G>T | 5'UTR (SNP) | VAF 10/67 reads (15%) | called by muse, varscan2
